Gene-level copy-number profile of tumor specimen ALCH-B3DK-TTP1-A from ALCHEMIST case ALCH-B3DK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.8 years (27,323 days).
Specimen ALCH-B3DK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d0fe9ee7-5c0d-41e5-8bea-684141fc1682.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3DK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,736 have no estimate.
https://portal.gdc.cancer.gov/files/0caa4c12-1986-43cf-81e4-525d68da87b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 570; copy number 1: 25,950; copy number 2: 25,687; copy number 3: 4,135; copy number 4: 2,520; copy number 5: 5; copy number 6: 5; copy number 7: 13; copy number 8: 1; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,792,796–15,793,285, 1 gene: RPL12P14.
- chr1:112,849,821–112,890,922, 2 genes (within-gene range 0–1): LINC01357, AL390729.1.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr3:184,725,013–184,773,178, 1 gene (within-gene range 0–1): LINC02069.
- chr6:57,919,784–57,930,291, 1 gene: GUSBP4.
- chr9:65,282,101–65,285,209, 1 gene: FOXD4L5.
- chr9:66,022,661–66,113,085, 5 genes (within-gene range 0–7): GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4.
- chr9:137,168,758–137,172,056, 4 genes (within-gene range 0–2): LRRC26, AL929554.1, MIR3621, TMEM210.
- chr10:8,050,450–8,053,484, 2 genes: GATA3-AS1, AL390294.1.
- chr13:19,152,567–19,181,824, 3 genes: SMPD4P2, AL139327.3, TUBA3C.
- chr15:25,178,738–25,197,656, 11 genes (within-gene range 0–1): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15.
- chr16:70,755,035–70,773,251, 3 genes (within-gene range 0–1): VAC14-AS1, AC020763.5, AC020763.2.
- chr17:16,847,635–16,854,309, 2 genes: KRT17P4, COTL1P1.
- chr17:61,361,668–61,400,243, 2 genes (within-gene range 0–2): AC005746.2, AC005746.1.
- chr19:19,512,418–19,537,581, 4 genes: TSSK6, NDUFA13, AC011448.1, YJEFN3.
- chr19:33,207,129–33,225,850, 3 genes (within-gene range 0–2): AC008738.7, SLC7A10, AC008738.4.
- chr19:54,102,728–54,115,675, 2 genes (within-gene range 0–2): NDUFA3, TFPT.
- chr22:24,101,689–24,103,354, 1 gene (within-gene range 0–1): AC253536.3.
- chr22:29,730,956–29,770,413, 4 genes (within-gene range 0–1): ZMAT5, Y_RNA, AC004882.3, UQCR10.
- chr22:38,426,327–38,483,447, 3 genes (within-gene range 0–2): KCNJ4, Z97056.3, KDELR3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–71,585, 3 genes, copy number 5: OR4G4P, OR4G11P, OR4F5.
- chr1:162,497,251–162,529,631, 1 gene, copy number 6: UHMK1.
- chr16:32,188,333–32,202,822, 3 genes, copy number 6: AC133485.5, AC133485.4, ABHD17AP8.
- chr16:32,439,069–32,441,159, 1 gene, copy number 5: PABPC1P13.
- chr16:32,475,051–32,478,250, 1 gene, copy number 8: ABCD1P3.
- chr16:32,649,193–32,788,944, 13 genes, copy number 7: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr21:43,053,191–43,076,943, 1 gene, copy number 6: CBS.
- chr22:21,125,660–21,142,371, 2 genes, copy number 5–11: POM121L7P, E2F6P2.

Autosomal genes at a single copy (total copy number 1): 23,658. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
